Somatic mutation profile of tumor specimen 0DACIS from CCDI case PBBJJP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.8 years (2,104 days).
Specimen 0DACIS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04bbc08f-0568-4aba-8f85-b9f98b2d1fe4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DACIX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/205d0dcc-51f4-4885-802e-1522895a3a2a

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, 3'UTR 2, 5'UTR 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHA2 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 100/437 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1171805040; called by muse, mutect2, varscan2
- PTEN | c.18A>C p.K6N | Missense Mutation (SNP) | VAF 152/1013 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as CD110185, COSV64292354, COSV64297759, COSV64298855; called by muse, varscan2
- RICTOR | c.2294C>T p.T765M | Missense Mutation (SNP) | VAF 47/1338 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs1303790479; called by muse, mutect2
- TTC28 | c.6671G>A p.S2224N | Missense Mutation (SNP) | VAF 19/395 reads (5%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1295379611; called by muse, mutect2
- EPPK1 | c.6548C>T p.A2183V | Missense Mutation (SNP) | VAF 64/680 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2
- KHDC1 | c.516C>T p.G172= (on ENST00000370384 / NM_001251874.2; = p.G99= on NM_030568.5) | Splice Region (SNP) | VAF 39/310 reads (13%) | called by muse, mutect2, varscan2
- MUC16 | c.24814C>A p.L8272M | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- USP9Y | c.5486A>G p.Y1829C | Missense Mutation (SNP) | VAF 164/301 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF264 | c.447G>T p.K149N | Missense Mutation (SNP) | VAF 23/326 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.112); called by muse, mutect2
- BECN2 | c.471C>T p.D157= | Silent (SNP) | VAF 28/948 reads (3%) | catalogued as rs907220506; called by muse, mutect2
- KCNH6 | c.1455C>T p.N485= | Silent (SNP) | VAF 116/899 reads (13%) | called by muse, mutect2, varscan2
- MTTP | c.2040C>T p.D680= | Silent (SNP) | VAF 59/647 reads (9%) | catalogued as rs559425917, COSV55510148; called by muse, mutect2
- CADM1 | c.*52A>C | 3'UTR (SNP) | VAF 39/328 reads (12%) | called by mutect2, varscan2
- FEZ1 | chr11:125496895 A>T | 5'Flank (SNP) | VAF 6/51 reads (12%) | called by muse, varscan2
- GAL | c.*88C>A | 3'UTR (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
- TXNDC12 | c.-64G>T | 5'UTR (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
